Somatic mutation profile of tumor specimen ASCProject_0045_T1_WES (aliquot ASCProject_0045_T1_WES_1) from CMI case ASCProject_0045, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 31.9 years (11,641 days).
Specimen ASCProject_0045_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 674908dd-0144-4fdb-a4d9-f37fd797fb47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0045_SALIVA (Saliva), aliquot ASCProject_0045_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7291968c-e753-468d-ace7-fb575858ac82

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Ins 3, 3'UTR 1, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 24/214 reads (11%) | catalogued as rs397515401, CM122406, COSV60107754, COSV60115393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 53/246 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as CD1010033; called by muse, mutect2, varscan2
- EPHA5 | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV56667605; called by muse, mutect2, varscan2
- FAM228B | c.678_680del p.R229del | In Frame Del (DEL) | VAF 37/138 reads (27%) | catalogued as rs1330410796; called by mutect2, pindel, varscan2
- FOXD4L5 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 71/612 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.665); catalogued as rs1563922530; called by muse, mutect2, varscan2
- H2BC1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.872); catalogued as rs143128181, COSV51236825; called by muse, mutect2
- LACTB | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs756244410; called by muse, mutect2, varscan2
- CDKN1C | c.99_100dup p.F34Sfs*10 | Frame Shift Ins (INS) | VAF 45/226 reads (20%) | called by mutect2, pindel, varscan2
- GPRC6A | c.142dup p.M48Nfs*20 | Frame Shift Ins (INS) | VAF 16/133 reads (12%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.838C>G p.H280D (on ENST00000642864 / NM_001111125.3; = p.H75D on NM_015075.2) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.215); called by muse, varscan2
- PLCB3 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRAMEF20 | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- PTK7 | c.3181C>G p.L1061V | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RP1L1 | c.3922_3923del p.E1308Rfs*18 | Frame Shift Del (DEL) | VAF 291/818 reads (36%) | called by pindel, varscan2
- SLC24A3 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VEGFD | c.69T>A p.S23R | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPOT | c.2324dup p.L776Afs*9 | Frame Shift Ins (INS) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- ZFP92 | c.628T>C p.C210R | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN5C | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERCC2 | c.1878C>T p.V626= | Silent (SNP) | VAF 97/370 reads (26%) | catalogued as rs891158158; called by muse, mutect2, varscan2
- ROBO2 | c.3153A>G p.K1051= | Silent (SNP) | VAF 80/352 reads (23%) | called by muse, mutect2, varscan2
- TEAD2 | c.951C>T p.A317= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs541250830; called by muse, mutect2, varscan2
- WBP4 | c.915G>A p.E305= | Silent (SNP) | VAF 61/288 reads (21%) | called by muse, mutect2, varscan2
- KNCN | c.*122C>T | 3'UTR (SNP) | VAF 19/99 reads (19%) | catalogued as rs374167291; called by muse, mutect2, varscan2
